Somatic mutation profile of tumor specimen C3N-01654-01 (aliquot CPT0121490006) from CPTAC case C3N-01654, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.1 years (23,413 days).
Specimen C3N-01654-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40cc6c7c-1810-40ee-9135-929465a7487c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01654-31 (Blood Derived Normal), aliquot CPT0121550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d399a5-f4d3-4bc3-aec7-6fac9e7d4536

The open-access MAF lists 86 somatic variants for this specimen: 65 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 14, Frame Shift Del 14, Intron 4, Frame Shift Ins 3, RNA 2, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GALT | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 139/570 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs201411551; called by muse, mutect2, varscan2
- ADAMTS2 | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778184902, COSV52381127; called by muse, mutect2
- ALK | c.2602C>G p.L868V | Missense Mutation (SNP) | VAF 110/488 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as COSV101201094; called by muse, mutect2, varscan2
- ARID1A | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 15/389 reads (4%) | catalogued as COSV61372664; called by muse, mutect2
- ARSK | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1442162208; called by muse, mutect2, varscan2
- DEFB123 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs747628781; called by muse, mutect2, varscan2
- EPHX2 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 99/451 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV66845162; called by muse, mutect2, varscan2
- FAM81B | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV51982434; called by muse, varscan2
- FGR | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs1048378161; called by muse, mutect2
- GSTO1 | c.433_435del p.E145del | In Frame Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs771562518; called by pindel, varscan2
- OR10P1 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV59008655; called by muse, mutect2
- SCN10A | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as COSV71862628; called by muse, mutect2, varscan2
- SETD2 | c.7386del p.S2463Pfs*4 | Frame Shift Del (DEL) | VAF 55/238 reads (23%) | catalogued as COSV57440619; called by mutect2, pindel, varscan2
- SH3GL3 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs778427582; called by muse, mutect2, varscan2
- SUFU | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766370528, COSV64018861; ClinVar: uncertain significance; called by muse, mutect2
- SYTL4 | c.1910G>A p.G637E | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868291409; called by muse, mutect2, varscan2
- TTN | c.89465G>A p.C29822Y (on ENST00000591111; = p.C22398Y on NM_003319.4) | Missense Mutation (SNP) | VAF 45/235 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs760317660; called by muse, mutect2, varscan2
- UGT2B7 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV100535260; called by muse, mutect2, varscan2
- UQCR11 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101650767; called by muse, mutect2, varscan2
- ACACA | c.3717C>G p.F1239L | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS16 | c.164T>C p.M55T | Missense Mutation (SNP) | VAF 99/408 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD11 | c.4130del p.G1377Afs*32 | Frame Shift Del (DEL) | VAF 98/518 reads (19%) | called by mutect2, pindel, varscan2
- BBS10 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BCOR | c.2742del p.F914Lfs*22 | Frame Shift Del (DEL) | VAF 58/276 reads (21%) | called by mutect2, pindel, varscan2
- CATSPERD | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNP | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- CDH11 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CLYBL | c.294T>A p.D98E | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.049); called by muse, varscan2
- CTDSPL2 | c.763T>C p.F255L | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DNASE1L1 | c.-88+3A>T | Splice Region (SNP) | VAF 45/197 reads (23%) | called by muse, mutect2, varscan2
- DSG3 | c.2716G>C p.G906R | Missense Mutation (SNP) | VAF 88/397 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- FAM131C | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 62/672 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2
- FLG | c.3265dup p.H1089Pfs*17 | Frame Shift Ins (INS) | VAF 152/629 reads (24%) | called by mutect2, varscan2
- GUCD1 | c.478T>G p.C160G | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- ITCH | c.1223A>C p.Q408P (on ENST00000262650 / NM_001257137.3; = p.Q367P on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- KCNQ5 | c.2648C>G p.T883R | Missense Mutation (SNP) | VAF 132/523 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KIF1A | c.683del p.K228Sfs*14 | Frame Shift Del (DEL) | VAF 56/259 reads (22%) | called by mutect2, pindel, varscan2
- KLC2 | c.1092_1096delinsA p.N364Kfs*13 | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by pindel, varscan2*
- LRP1 | c.7505_7512del p.N2502Mfs*10 | Frame Shift Del (DEL) | VAF 59/279 reads (21%) | called by mutect2, pindel, varscan2
- MAP3K8 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP4K1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MGAM2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGAT4B | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MORC3 | c.2320C>G p.Q774E | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSX1 | c.686_690dup p.Q231Dfs*10 | Frame Shift Ins (INS) | VAF 81/375 reads (22%) | called by mutect2, pindel, varscan2
- MUC17 | c.4165T>C p.S1389P | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NLRP13 | c.3071del p.G1024Vfs*9 | Frame Shift Del (DEL) | VAF 33/172 reads (19%) | called by mutect2, pindel, varscan2
- NOG | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- OR10J3 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- PBRM1 | c.15_16del p.R6Kfs*14 | Frame Shift Del (DEL) | VAF 40/137 reads (29%) | called by mutect2, pindel, varscan2
- PHF23 | c.149del p.P50Lfs*82 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by pindel, varscan2
- PHF23 | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- PRPS2 | c.4C>A p.P2T | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RWDD2B | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SRPK1 | c.854_866del p.R285Lfs*29 | Frame Shift Del (DEL) | VAF 59/402 reads (15%) | called by mutect2, pindel, varscan2
- TM9SF3 | c.1701_1702del p.C567Wfs*18 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by pindel, varscan2
- TNPO2 | c.2451G>T p.K817N (on ENST00000425528 / NM_001382240.1; = p.K807N on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIOBP | c.5033T>A p.L1678Q | Missense Mutation (SNP) | VAF 27/509 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2
- TRIQK | c.54del p.K18Nfs*20 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- TRPV3 | c.1156T>A p.S386T | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TSPAN13 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- VHL | c.574_578del p.P192Cfs*62 | Frame Shift Del (DEL) | VAF 112/473 reads (24%) | called by mutect2, pindel, varscan2
- ZNF232 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ZNF330 | c.493del p.C165Afs*4 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- ZNF595 | c.864_865dup p.C289Yfs*12 | Frame Shift Ins (INS) | VAF 28/237 reads (12%) | called by mutect2, varscan2
- ANKFN1 | c.3261C>T p.P1087= (on ENST00000653862; = p.P940= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 104/496 reads (21%) | catalogued as COSV101633447; called by muse, mutect2, varscan2
- ARHGEF18 | c.2232G>A p.S744= (on ENST00000359920 / NM_001130955.2; = p.S640= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/338 reads (5%) | catalogued as rs771022719; called by muse, mutect2
- C4orf54 | c.2595G>A p.Q865= | Silent (SNP) | VAF 81/292 reads (28%) | called by muse, mutect2, varscan2
- CCDC83 | c.1206C>T p.S402= (on ENST00000342404 / NM_001286159.2; = p.S433= on NM_173556.5) | Silent (SNP) | VAF 24/149 reads (16%) | called by muse, varscan2
- CRYBG3 | c.2151T>G p.P717= | Silent (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- LRFN1 | c.78G>A p.A26= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2
- LY6H | c.165C>T p.V55= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- MAP3K6 | c.2691C>T p.A897= | Silent (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- PLCG2 | c.3048G>C p.T1016= | Silent (SNP) | VAF 65/230 reads (28%) | called by muse, mutect2, varscan2
- PRMT8 | c.639T>A p.L213= | Silent (SNP) | VAF 93/407 reads (23%) | called by muse, mutect2, varscan2
- PRSS36 | c.171C>A p.T57= | Silent (SNP) | VAF 70/356 reads (20%) | called by muse, mutect2, varscan2
- RPS6KA5 | c.2331C>G p.T777= | Silent (SNP) | VAF 62/277 reads (22%) | catalogued as rs1177229887; called by muse, mutect2, varscan2
- SECISBP2 | c.132C>T p.P44= | Silent (SNP) | VAF 111/407 reads (27%) | called by muse, mutect2, varscan2
- SUDS3 | c.825C>T p.I275= | Silent (SNP) | VAF 43/419 reads (10%) | catalogued as COSV64348694; called by muse, mutect2, varscan2
- C8orf86 | n.906C>T | RNA (SNP) | VAF 64/265 reads (24%) | called by muse, mutect2, varscan2
- CCDC78 | c.1134-22C>T | Intron (SNP) | VAF 113/473 reads (24%) | called by muse, mutect2, varscan2
- COG5 | c.1686+1496C>G | Intron (SNP) | VAF 53/236 reads (22%) | called by muse, mutect2, varscan2
- LINC01537 | n.242C>G | RNA (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- MZB1 | c.177+287C>T | Intron (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- PDXDC1 | chr16:14974731 T>A | 5'Flank (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- TRAK1 | c.287-25428C>T | Intron (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
